Gene-level copy-number profile of tumor specimen TCGA-AG-3594-01A from TCGA case TCGA-AG-3594, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.4 years (28,277 days).
Specimen TCGA-AG-3594-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.5b5029e7-1d01-4c74-8cd0-585359f12766.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3594-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4945b485-e179-44c1-b7cb-1858bcdc7259

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,359; copy number 2: 44,410; copy number 3: 6,407; copy number 4: 309; copy number 5: 285; copy number 7: 18; copy number 13: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3594-01A-02D-0819-01): tumor purity 0.63, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 329 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:33,226,848–39,105,445, 114 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–1,057,552, 26 genes, copy number 13: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2.
- chr9:4,299,390–10,632,203, 96 genes, copy number 5–7 (broad region; genes not listed).
- chr9:12,287,320–13,323,450, 13 genes, copy number 7: JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1.
- chr9:13,406,380–13,488,125, 1 gene, copy number 7: LINC01235.
- chr9:14,921,013–15,544,294, 14 genes, copy number 5: CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:15,588,355–15,588,615, 1 gene, copy number 5: HMGN2P16.
- chr9:20,331,446–20,622,499, 6 genes, copy number 5: AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1.
- chr9:20,683,304–20,787,055, 3 genes, copy number 5: FOCAD-AS1, MIR491, SNORA30B.
- chr9:22,703,516–23,438,700, 1 gene, copy number 5 (within-gene range 3–5): AL391117.1.
- chr9:23,291,544–24,592,104, 13 genes, copy number 5: AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.
- chr13:26,254,104–27,989,584, 41 genes, copy number 5 (within-gene range 1–5): CDK8, AL159159.1, AL353789.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P.

Autosomal genes at a single copy (total copy number 1): 7,327. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
